Somatic mutation profile of tumor specimen C3L-03387-01 (aliquot CPT0224330009) from CPTAC case C3L-03387, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 70.7 years (25,839 days).
Specimen C3L-03387-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fa3cf9cf-4760-483a-abf2-4ba07baa6554.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03387-31 (Blood Derived Normal), aliquot CPT0226180002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/03fa7ecc-0ca4-4f36-a0c8-1d9f7afa8d95

The open-access MAF lists 106 somatic variants for this specimen: 67 protein-altering or splice-affecting, 24 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 24, Intron 7, RNA 5, Nonsense Mutation 3, Frame Shift Del 2, 5'UTR 2, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMC6 | c.1090A>G p.I364V (on ENST00000392336; = p.I339V on NM_033415.4) | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.101); catalogued as rs1462611005, COSV99522955; called by muse, mutect2, varscan2
- ATP13A1 | c.3010G>A p.V1004I | Missense Mutation (SNP) | VAF 48/327 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs752349534, COSV52283037; called by muse, mutect2, varscan2
- CAPSL | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs368551299, COSV68438743; called by muse, mutect2, varscan2
- CCDC171 | c.2161C>G p.Q721E | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs772486231, COSV52654129; called by muse, mutect2, varscan2
- CFAP65 | c.2068C>T p.R690* | Nonsense Mutation (SNP) | VAF 30/101 reads (30%) | catalogued as rs531146350, COSV58563871; called by muse, mutect2, varscan2
- CLDN14 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 66/237 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.207); catalogued as rs768382153; called by muse, mutect2, varscan2
- CYP4X1 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs964059939, COSV100903356; called by muse, mutect2, varscan2
- DSG3 | c.1418C>T p.T473M | Missense Mutation (SNP) | VAF 58/146 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as rs200551780; called by muse, mutect2, varscan2
- EMC7 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV99855017; called by muse, mutect2, varscan2
- FANCM | c.3763C>A p.P1255T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs770651053; called by muse, mutect2, varscan2
- FGD5 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs568677261, COSV53241485; called by muse, mutect2, varscan2
- GABRA6 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs754862222, COSV50877427; called by muse, mutect2, varscan2
- GJA4 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 91/241 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.104); catalogued as rs774721432, COSV60725778; called by muse, mutect2
- HECTD4 | c.11707G>A p.A3903T | Missense Mutation (SNP) | VAF 95/382 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs536620571, COSV66392303; called by muse, mutect2, varscan2
- IRGC | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 54/283 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs775899801, COSV54983667; called by muse, mutect2, varscan2
- LILRA2 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 109/542 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.268); catalogued as COSV52192179, COSV52196813; called by muse, mutect2, varscan2
- LILRB1 | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 61/384 reads (16%) | SIFT tolerated (0.98); PolyPhen benign (0.035); catalogued as rs955866600, COSV61120537; called by muse, mutect2, varscan2
- LRP2 | c.4999C>T p.R1667* | Nonsense Mutation (SNP) | VAF 86/250 reads (34%) | catalogued as rs867941074, COSV55558193; called by muse, mutect2, varscan2
- MRGPRF | c.896C>T p.S299L | Missense Mutation (SNP) | VAF 101/286 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as rs1296210806; called by muse, mutect2, varscan2
- MUC4 | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 66/162 reads (41%) | SIFT tolerated, low confidence (0.66); PolyPhen possibly damaging (0.494); catalogued as rs756574492, COSV62200722; called by muse, mutect2, varscan2
- OR6K3 | c.418G>A p.V140I (on ENST00000368146; = p.V124I on NM_001005327.2) | Missense Mutation (SNP) | VAF 80/254 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs773825307, COSV63746516; called by muse, mutect2, varscan2
- OR7A17 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.945); catalogued as rs749086811; called by muse, mutect2, varscan2
- PAN2 | c.3353G>A p.R1118Q (on ENST00000425394 / NM_001127460.3; = p.R1114Q on NM_014871.5) | Missense Mutation (SNP) | VAF 76/246 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV56265084; called by muse, mutect2, varscan2
- PCDHB8 | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 211/1218 reads (17%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.007); catalogued as rs1414157434, COSV99175991; called by muse, mutect2, varscan2
- PLA2G4D | c.1091C>T p.T364M | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs371423362; called by muse, mutect2, varscan2
- PUS1 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 161/537 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1022672949; called by muse, mutect2, varscan2
- RAB40A | c.380G>A p.R127H | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100420972; called by muse, mutect2
- RAD21 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as rs149171113; called by muse, mutect2, varscan2
- RASEF | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 120/590 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1463156239; called by muse, mutect2, varscan2
- RAX | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 123/459 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV56873927; called by muse, mutect2, varscan2
- RYR2 | c.4444C>T p.R1482C | Missense Mutation (SNP) | VAF 91/308 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.825); catalogued as rs564869863, COSV63679506; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR2 | c.4975C>T p.R1659W | Missense Mutation (SNP) | VAF 55/169 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1483097607, COSV63681954; called by muse, mutect2, varscan2
- SCN4A | c.4930G>A p.V1644M | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs775486265, COSV71125648; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC22A11 | c.595del p.L199Cfs*14 | Frame Shift Del (DEL) | VAF 91/306 reads (30%) | catalogued as COSV100102606; called by mutect2, pindel, varscan2
- SLC9A2 | c.1838G>A p.R613H | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1444790071; called by muse, mutect2, varscan2
- TMEM200A | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772523704, COSV51659526; called by muse, mutect2, varscan2
- TRIM54 | c.742G>A p.G248S (on ENST00000380075 / NM_187841.3; = p.G290S on NM_032546.4) | Missense Mutation (SNP) | VAF 126/404 reads (31%) | SIFT tolerated (0.86); PolyPhen benign (0.02); catalogued as rs753597613, COSV51991443; called by muse, mutect2, varscan2
- TTLL5 | c.3688C>G p.P1230A | Missense Mutation (SNP) | VAF 81/191 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100091353; called by muse, mutect2, varscan2
- USP29 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs767708929, COSV54243085; called by muse, varscan2
- ZBED9 | c.2722G>A p.D908N | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs745394917, COSV101509344; called by muse, mutect2, varscan2
- AHRR | c.603G>C p.R201S | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ANKRD36 | c.2530G>A p.D844N | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- BRD8 | c.713G>A p.G238E (on ENST00000254900 / NM_139199.2; = p.G311E on NM_006696.4) | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- BTG4 | c.346T>G p.S116A | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.11); called by muse, varscan2
- CCBE1 | c.1127G>A p.S376N | Missense Mutation (SNP) | VAF 23/645 reads (4%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.001); called by muse, mutect2
- DRD5 | c.131C>T p.A44V | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2
- ECPAS | c.4355C>A p.S1452Y | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); called by muse, varscan2
- EPS8L3 | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- FAM135B | c.542G>C p.S181T | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FOXL2 | c.1028T>C p.L343P | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.675); called by muse, mutect2
- GDA | c.184C>G p.P62A | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- GIMAP6 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 11/335 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- GLUD2 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 129/243 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- GSG1L2 | c.245dup p.F83Vfs*21 | Frame Shift Ins (INS) | VAF 98/269 reads (36%) | called by mutect2, pindel, varscan2
- JUND | c.348_350del p.T117del | In Frame Del (DEL) | VAF 116/486 reads (24%) | called by pindel, varscan2
- KLF3 | c.904del p.A302Lfs*6 | Frame Shift Del (DEL) | VAF 26/87 reads (30%) | called by mutect2, pindel, varscan2
- MAP2 | c.1709C>A p.S570Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MUCL1 | c.38A>T p.K13I | Missense Mutation (SNP) | VAF 74/258 reads (29%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2, varscan2
- MYO15A | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 97/403 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- PCDHB8 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 74/666 reads (11%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PKHD1 | c.10839C>G p.D3613E | Missense Mutation (SNP) | VAF 61/184 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- PRR16 | c.41C>G p.P14R | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.191); called by muse, mutect2
- RASEF | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 121/593 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCN8A | c.4434C>A p.D1478E | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by mutect2, varscan2
- SMARCD2 | c.1255C>T p.Q419* | Nonsense Mutation (SNP) | VAF 75/260 reads (29%) | called by muse, mutect2, varscan2
- SOCS4 | c.1036G>A p.A346T | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TNPO2 | c.560A>G p.K187R | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2
- ALOX12B | c.1992G>A p.A664= | Silent (SNP) | VAF 12/144 reads (8%) | catalogued as rs1374842602; called by muse, mutect2
- ANO1 | c.2610G>A p.P870= | Silent (SNP) | VAF 59/168 reads (35%) | catalogued as rs779132744; called by muse, mutect2, varscan2
- C3 | c.1923C>T p.D641= | Silent (SNP) | VAF 40/678 reads (6%) | catalogued as rs113044084; called by muse, mutect2
- CGB3 | c.48C>T p.G16= | Silent (SNP) | VAF 31/465 reads (7%) | catalogued as rs936363148; called by muse, mutect2, varscan2
- COL1A1 | c.2166C>T p.G722= | Silent (SNP) | VAF 50/186 reads (27%) | catalogued as rs200188855, COSV99868335; ClinVar: likely benign; called by muse, mutect2, varscan2
- CST6 | c.27G>A p.A9= | Silent (SNP) | VAF 10/178 reads (6%) | called by muse, mutect2
- DNAJB2 | c.342A>G p.A114= | Silent (SNP) | VAF 75/312 reads (24%) | called by muse, mutect2, varscan2
- DOK6 | c.948G>A p.S316= | Silent (SNP) | VAF 23/342 reads (7%) | catalogued as rs978843273; called by muse, mutect2
- FOXC1 | c.1368C>G p.G456= | Silent (SNP) | VAF 10/188 reads (5%) | called by muse, mutect2
- GDA | c.186G>T p.P62= | Silent (SNP) | VAF 46/176 reads (26%) | catalogued as COSV52997154; called by muse, mutect2
- HOXC12 | c.447C>T p.D149= | Silent (SNP) | VAF 61/225 reads (27%) | called by muse, mutect2, varscan2
- IRS4 | c.1485A>G p.S495= | Silent (SNP) | VAF 208/312 reads (67%) | catalogued as COSV64536384; called by muse, mutect2, varscan2
- ITGA2B | c.2061C>T p.G687= | Silent (SNP) | VAF 83/221 reads (38%) | catalogued as rs777406811; called by muse, mutect2, varscan2
- MYO1F | c.1944C>T p.D648= | Silent (SNP) | VAF 87/296 reads (29%) | catalogued as rs758730779; called by muse, mutect2, varscan2
- NEFM | c.786G>A p.L262= | Silent (SNP) | VAF 265/769 reads (34%) | called by muse, mutect2, varscan2
- OSBPL2 | c.816G>A p.P272= (on ENST00000313733 / NM_144498.4; = p.P260= on NM_014835.4) | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs376209465; called by muse, mutect2, varscan2
- OTOP3 | c.1461C>T p.G487= | Silent (SNP) | VAF 124/393 reads (32%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2283G>A p.A761= | Silent (SNP) | VAF 121/471 reads (26%) | catalogued as rs1324598241, COSV53946866; called by muse, mutect2, varscan2
- SLC49A4 | c.1188C>T p.S396= | Silent (SNP) | VAF 45/167 reads (27%) | catalogued as rs150962928; called by muse, mutect2, varscan2
- TENT5D | c.699T>A p.G233= | Silent (SNP) | VAF 13/59 reads (22%) | called by muse, mutect2, varscan2
- TFAP2B | c.516C>G p.G172= | Silent (SNP) | VAF 61/354 reads (17%) | called by muse, mutect2, varscan2
- TMPRSS3 | c.1056C>T p.D352= | Silent (SNP) | VAF 101/331 reads (31%) | catalogued as rs397517369, COSV52301670; ClinVar: likely benign; called by muse, mutect2, varscan2
- TSC2 | c.1170G>A p.T390= | Silent (SNP) | VAF 39/624 reads (6%) | catalogued as rs376144933; ClinVar: benign / likely benign; called by muse, mutect2
- VPS13C | c.4461T>G p.S1487= (on ENST00000644861 / NM_020821.3; = p.S1444= on NM_017684.5) | Silent (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- CASP10 | c.685-3244C>T | Intron (SNP) | VAF 49/182 reads (27%) | catalogued as rs773609733; called by muse, mutect2, varscan2
- CHP2 | c.140+14G>A | Intron (SNP) | VAF 91/164 reads (55%) | catalogued as rs996728384; called by muse, mutect2, varscan2
- DDX49 | c.448-23C>T | Intron (SNP) | VAF 111/397 reads (28%) | catalogued as rs1236518623; called by muse, mutect2, varscan2
- EP400P1 | n.782G>A | RNA (SNP) | VAF 111/451 reads (25%) | catalogued as rs1183453948; called by muse, mutect2, varscan2
- IGFN1 | c.1242-1394G>C | Intron (SNP) | VAF 69/195 reads (35%) | called by muse, mutect2, varscan2
- IGHEP1 | n.626C>T | RNA (SNP) | VAF 23/407 reads (6%) | catalogued as rs767318108; called by muse, mutect2
- KRT14 | c.1322-19C>G | Intron (SNP) | VAF 40/120 reads (33%) | called by muse, mutect2, varscan2
- MLXIPL | c.2441-49G>A | Intron (SNP) | VAF 48/216 reads (22%) | catalogued as rs1417035753; called by muse, varscan2
- PEG10 | c.-261C>A | 5'UTR (SNP) | VAF 61/243 reads (25%) | called by muse, mutect2, varscan2
- POU2F2 | c.*70G>A | 3'UTR (SNP) | VAF 38/147 reads (26%) | catalogued as rs578085962; called by muse, mutect2, varscan2
- PSG9 | c.1243+64A>G | Intron (SNP) | VAF 57/254 reads (22%) | called by muse, mutect2, varscan2
- RASA4CP | n.529C>T | RNA (SNP) | VAF 24/892 reads (3%) | catalogued as rs1457212839; called by muse, mutect2
- SSTR5-AS1 | n.657C>T | RNA (SNP) | VAF 21/55 reads (38%) | catalogued as rs748847969; called by muse, mutect2, varscan2
- TBXA2R | c.-29G>A | 5'UTR (SNP) | VAF 39/202 reads (19%) | catalogued as rs1385575052; called by muse, mutect2, varscan2
- ZNF849P | n.964C>A | RNA (SNP) | VAF 18/334 reads (5%) | called by muse, mutect2
